Gene-level copy-number profile of tumor specimen TCGA-OR-A5K5-01A from TCGA case TCGA-OR-A5K5, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 60.0 years (21,907 days).
Specimen TCGA-OR-A5K5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.b50c051b-5569-418c-8b3d-5dde7eb77824.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5K5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bc8c172e-6a1e-4c2b-a4b9-42644dceedea

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 243; copy number 2: 9,934; copy number 3: 25,831; copy number 4: 19,554; copy number 5: 2,240; copy number 6: 1,940; copy number 7: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5K5-01A-11D-A29H-01): tumor purity 0.88, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,686,182–182,145,249, 5 genes: AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1.
- chr4:182,144,852–182,190,382, 2 genes: AC108142.1, MIR1305.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 65 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,002,630–155,563,162, 39 genes, copy number 7 (within-gene range 4–7): ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4.
- chr12:109,111,218–109,663,183, 12 genes, copy number 7 (within-gene range 6–7): AC007637.1, ACACB, FOXN4, MYO1H, LINC01486, AC007570.1, KCTD10, UBE3B, MMAB, RNU4-32P, MVK, RN7SKP250.
- chr19:18,831,959–19,138,513, 14 genes, copy number 7: UPF1, GDF1, CERS1, AC005197.1, COPE, AC002985.1, DDX49, HOMER3, HOMER3-AS1, RN7SL70P, SUGP2, ARMC6, SLC25A42, TMEM161A.

Autosomal genes at a single copy (total copy number 1): 243. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
